Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3MR, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3MR-06A (Metastatic).

1C0-0-3

Melanoma, NOS 8720/3

Site: Subcutaneous tissue, NOS C49.9

hw 1/7/12

DIAGNOSIS

Patient ID - Sample ID -

- (A) RIGHT SUPERFICIAL FEMORAL CONTENTS:
METASTATIC MALIGNANT MELANOMA IN FIBROADIPOSE TISSUE.
TUMOR SIZE IS 40.0 X 40.0 MM.
Ten lymph nodes, no melanoma identified (0/10).

- (B) CLOQUET'S NODE:
One lymph node, no melanoma identified (0/1).

- (C) COMMON AND EXTERNAL ILIAC AND OBTURATOR NODES:
Eleven lymph nodes, no melanoma identified (0/11).

- (D) LATERAL SKIN MARGIN:
Skin and subcutaneous tissue, no tumor identified.

- (E) MEDIAL SKIN MARGIN:
Skin and subcutaneous tissue, no tumor identified.

Entire report and diagnosis completed by

Source: NCI Genomic Data Commons file 4b0b77a0-4e0a-4c65-b6dc-b54a5d9aa7c5 (TCGA-D3-A3MR.E77E1BEF-E39E-415E-B8F8-BB73BE263C6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).